Surgical pathology report (de-identified scan), TCGA case TCGA-B1-5398, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B1-5398-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Right renal mass
PROCEDURE: Right radical nephrectomy
SPECIFIC CLINICAL QUESTION: No
OUTSIDE TISSUE DIAGNOSIS: No
PRIOR MALIGNANCY: No
CHEMORADIATION THERAPY: No
ORGAN TRANSPLANT: No
IMMUNOSUPPRESSION: No
OTHER DISEASES: No

FINAL DIAGNOSIS:**KIDNEY, RIGHT, RADICAL NEPHRECTOMY -**

- A. PAPILLARY RENAL CELL CARCINOMA, TYPE 2.
- B. FUHRMAN NUCLEAR GRADE IS 3 OF 4.
- C. THE CARCINOMA MEASURES 9.0 CM IN GREATEST DIMENSION.
- D. THE CARCINOMA GROSSLY INVADIES THE RENAL VEIN AND IS SEEN EXTENDING BEYOND THE RENAL VEIN RESECTION MARGIN.
- E. THE NON-NEOPLASTIC KIDNEY SHOWS INTERSTITIAL INFLAMMATION, GLOMERULOSCLEROSIS AND ARTERIOSCLEROSIS.
- F. PATHOLOGICAL STAGE: pT3a N0 MX (SEE SYNOPTIC).

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY KIDNEY TUMORS**

SPECIMEN TYPE:	Radical nephrectomy
LATERALITY:	Right
TUMOR SITE:	Middle
FOCALITY:	Unifocal
TUMOR SIZE:	Greatest dimension: 9.0 cm Additional dimensions: 7.0 x 5.5 cm
MACROSCOPIC EXTENT OF TUMOR:	Tumor extension into major veins
HISTOLOGIC TYPE:	Papillary renal cell carcinoma
HISTOLOGIC GRADE (Fuhrman Nuclear Grade):	G3
PATHOLOGIC STAGING (pTNM):	pT3a pNX Number of regional lymph nodes examined: 0
MARGINS:	pMX Margin(s) involved by invasive carcinoma Renal vein margin
ADRENAL GLAND:	Not present
LYMPH-VASCULAR INVASION (LVI):	Present/identified
ADDITIONAL PATHOLOGIC FINDINGS:	Inflammation (type): chronic interstitial inflammation Glomerular disease (type): glomerulosclerosis
KIDNEY-RESIDUAL TUMOR (R):	R2

Source: NCI Genomic Data Commons file ffcaaa91-172c-44a0-a31b-2d35501e547f (TCGA-B1-5398.02449FCA-208F-4748-9139-B883D226B955.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).